Surgical pathology report (de-identified scan), TCGA case TCGA-BQ-7048, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BQ-7048-01A (Primary Tumor).

[page 1 of 3]
Patient Name

Med. Rec. #:

DOB:

Gender:

Ref. Physician:

Patient Address:

Ref. Source:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Prognosis & History:

with left renal mass.

Specimens Submitted:

1: SP: Left kidney and adrenal gland

2: SP: Left para-aortic lymph nodes

3: SP: Left retroperitoneal fat

DIAGNOSIS:

- 1) KIDNEY AND ADRENAL GLAND, LEFT; RADICAL NEPHRECTOMY:
- RENAL CELL CARCINOMA, TYPE UNCLASSIFIED, NUCLEAR GRADE III/IV.
- THE PATTERN OF GROWTH IS ACINAR AND PAPILLARY.
- THE TUMOR GREATEST DIAMETER IS 11 CM.
- THE TUMOR EXTENDS THROUGH THE RENAL CAPSULE BUT IS CONFINED WITHIN GEROTA'S FASCIA.
- NO INVASION OF THE RENAL VEIN IS IDENTIFIED.
- ALL SURGICAL MARGINS ARE FREE OF TUMOR.
- THE NON-NEOPLASTIC KIDNEY IS UNREMARKABLE.
- THE ADRENAL GLAND SHOWS A 1.7 CM ADRENOCORTICAL ADENOMA.
- THE LYMPH NODE STATUS IS AS FOLLOWS (EXPRESSED AS THE NUMBER OF METASTATIC NODES IN RELATION TO THE TOTAL NUMBER OF NODES EXAMINED): RENAL HILAR: 0/3.
- 2) LYMPH NODES, LEFT PARA-AORTIC; EXCISION:
- EIGHT BENIGN LYMPH NODES (0/8).
- 3) ADIPOSE TISSUE, LEFT RETROPERITONEAL; BIOPSY:
- BENIGN ADIPOSE TISSUE.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Special Studies:

Result

Special Stain

Comment

RECUT

RECUT

RECUT

[page 2 of 3]
SURGICAL PATHOLOGY REPORT

1) The specimen is received fresh for frozen section diagnosis, labeled, "Left kidney and adrenal gland (freeze mass)". It consists of a radical nephrectomy specimen measuring 21.0 x 13.0 x 9.0 cm and weighing 1250 grams total. There is a 11.0 x 0.5 x 0.5 cm segment of ureter attached. The specimen is inked black and opened to show the kidney measuring 12.0 x 8.0 x 6.0 cm. There is a 8.0 x 6.0 x 6.0 cm multinodular yellow mass in the cortex extending into the perirenal fat. There are also multiple black firm nodules in the perirenal fat, measuring up to 1.1 cm in greatest dimension. Adjacent to the mass is a 3.0 x 3.0 x 2.0 cm area of kidney, which is mottled in appearance. The remainder of the kidney, pelvis and renal vein are grossly unremarkable without tumor. The hilum is dissected to show multiple lymph nodes, measuring up to 1.5 cm in greatest dimension. The adrenal gland measures 6.2 x 3.0 x 1.4 cm and weighs 11 grams. There is a yellow, well-encapsulated, cortical nodule, measuring up to 1.7 cm in greatest dimension. Representative sections are submitted.

Summary of Sections:

FSC – frozen section control

UM – ureter margin

VM – vascular margin

LN – hilar lymph nodes

T – tumor

TC – tumor with cortex

TP – tumor with pelvis

MK – mottled kidney

TF – tumor bulging into fat

TNF – tumor nodules in fat

M – margin closest to tumor and fat

A – adrenal

2) The specimen is received in formalin, labeled "Left para-aortic lymph nodes". It consists of multiple pieces of fibrofatty tissues measuring 5.5 x 4.0 x 1.0 cm. Serial sectioning reveals multiple lymph nodes ranging from 0.5 up to 1.5 cm in greatest dimension. The largest lymph node was bisected. The nodes were entirely submitted.

Summary of Section:

LN - lymph nodes

BLN - bisected lymph node

3) The specimen is received in formalin, labeled "Left retroperitoneal fat". It consists of a single piece of unremarkable fatty tissue measuring 7.0 x 4.0 x 1.0 cm. Representative sections submitted.

Summary of Sections:

U - undesignated

Summary of Sections:

Part 1: SP: Left kidney and adrenal gland

Block	Sect. Site	PCs
5	A	5
1	FSC	1
2	LN	3
1	M	1
2	MK	2
3	T	3
1	TC	1
2	TF	2
2	TNF	2
1	TP	1
1	UM	1
1	VM	1

Part 2: SP: Left para-aortic lymph nodes (II)

[page 3 of 3]
Block	Sect. Site	PCs
2	BLN	2
2	LN	4

Part 3: SP: Left retroperitoneal fa

Block	Sect. Site	PCs
1	U	2

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: RENAL CORTICAL CARCINOMA
PERMANENT DIAGNOSIS: SAME

Source: NCI Genomic Data Commons file f1524560-befd-46cb-a679-6f1ede326349 (TCGA-BQ-7048.AD25402A-E67F-4E9E-BCDC-F8F419C69172.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).